Somatic mutation profile of tumor specimen TCGA-P6-A5OH-01A (aliquot TCGA-P6-A5OH-01A-11D-A30A-10) from TCGA case TCGA-P6-A5OH, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 59.2 years (21,627 days).
Specimen TCGA-P6-A5OH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39ddb5eb-ad4c-40c7-b793-a2dce1e3790a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P6-A5OH-11A (Solid Tissue Normal), aliquot TCGA-P6-A5OH-11A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdd611bf-614a-41cd-87da-1040c8bc68c2

The open-access MAF lists 130 somatic variants for this specimen: 103 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 81, Silent 27, In Frame Del 7, Frame Shift Del 7, Nonsense Mutation 6, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.12117G>C p.K4039N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV67994148; called by muse, mutect2
- AFF3 | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150108936, COSV100420512; called by muse, mutect2, varscan2
- CADM3 | c.1111G>A p.D371N (on ENST00000368125 / NM_001127173.3; = p.D405N on NM_021189.5) | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761281047, COSV63671716, COSV63673990; called by muse, mutect2, varscan2
- CDHR5 | c.262_264del p.E88del | In Frame Del (DEL) | VAF 38/299 reads (13%) | catalogued as rs1257776158; called by mutect2, pindel, varscan2
- CEACAM6 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV52269555; called by muse, mutect2
- CHSY3 | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59270272; called by muse, mutect2, varscan2
- CREB3L3 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99314301; called by mutect2, varscan2
- CYP2B6 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs138912615; called by muse, mutect2, varscan2
- DBN1 | c.1367A>C p.D456A | Missense Mutation (SNP) | VAF 132/670 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs775591763; called by muse, mutect2
- FKBP4 | c.1286C>G p.A429G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs770611717; called by muse, mutect2, varscan2
- GPANK1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs750632291; called by muse, mutect2, varscan2
- HK2 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1264600281; called by muse, mutect2, varscan2
- HTR3D | c.1202G>A p.G401D (on ENST00000382489 / NM_001163646.2; = p.G226D on NM_182537.3) | Missense Mutation (SNP) | VAF 66/439 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV100488397; called by muse, mutect2, varscan2
- KCND2 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV58568834; called by muse, mutect2, varscan2
- LGALS3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778604374; called by muse, mutect2, varscan2
- LRMDA | c.43A>T p.K15* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | catalogued as COSV65284185; called by muse, mutect2, varscan2
- MARCHF10 | c.2422G>A p.V808I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as rs755150781; called by muse, mutect2, varscan2
- NPAP1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100275800, COSV61508196; called by muse, mutect2, varscan2
- OIT3 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs139078371; called by muse, mutect2
- OR10Q1 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as rs1467390122, COSV57470726; called by muse, mutect2
- OR52D1 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542670667; called by muse, mutect2, varscan2
- OR5M1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV73202080; called by muse, mutect2, varscan2
- OTUB2 | c.255_257del p.L86del | In Frame Del (DEL) | VAF 58/231 reads (25%) | catalogued as rs1434073932; called by mutect2, pindel, varscan2
- PACSIN2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs749432192, COSV99606230; called by muse, mutect2, varscan2
- PCDH15 | c.5144G>T p.R1715I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV57347781; called by muse, mutect2, varscan2
- PEG3 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV55644106; called by muse, mutect2, varscan2
- PI4KA | c.2176G>C p.V726L | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs779863269; called by muse, mutect2, varscan2
- PROKR1 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs147256235; called by muse, mutect2, varscan2
- PTPN9 | c.463_464del p.M155Vfs*4 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs1325317760; called by mutect2, pindel, varscan2
- RBPJL | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1202411768; called by muse, mutect2
- RFC5 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57478206; called by muse, mutect2, varscan2
- SCAF1 | c.3385C>G p.Q1129E | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs779360567; called by muse, mutect2, varscan2
- SCAP | c.3703_3706del p.T1235Sfs*? | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as rs746678809; called by pindel, varscan2
- SETBP1 | c.2281G>A p.V761M | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745506540, COSV56325165; called by muse, mutect2, varscan2
- TGOLN2 | c.1155_1157del p.F386del | In Frame Del (DEL) | VAF 40/258 reads (16%) | catalogued as rs1158578968; called by pindel, varscan2
- TRIM9 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.593); catalogued as COSV100031605; called by muse, mutect2
- UBB | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV56219779; called by muse, mutect2, varscan2
- UNKL | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as rs1438788838; called by muse, mutect2
- VPS13A | c.5047_5049del p.T1683del | In Frame Del (DEL) | VAF 19/112 reads (17%) | catalogued as rs1440066235; called by mutect2, pindel, varscan2
- ZNF474 | c.84C>G p.N28K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs748043251, COSV99682274; called by muse, mutect2, varscan2
- ADCY7 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- ALPK1 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ANLN | c.152_154del p.Q51del | In Frame Del (DEL) | VAF 18/80 reads (23%) | called by pindel, varscan2
- ASTE1 | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ASXL3 | c.3701A>T p.N1234I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- BECN1 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C1S | c.1364T>A p.F455Y | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- CAND1 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CDH1 | c.2560_2563del p.D854Kfs*8 | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | called by mutect2, pindel, varscan2
- CENPQ | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- CEP128 | c.1225C>G p.L409V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CIC | c.2771T>A p.V924E | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CMBL | c.239_254del p.V80Gfs*14 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel
- DBN1 | c.578A>C p.E193A | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- DMRTC2 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAH17 | c.12559del p.A4187Qfs*11 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | called by mutect2, pindel, varscan2
- DNPEP | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EGFLAM | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, varscan2
- EML1 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- FAM120A | c.2471T>C p.L824P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCF | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAT3 | c.13581A>T p.E4527D | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- FBXO38 | c.3347C>G p.P1116R (on ENST00000340253 / NM_205836.3; = p.P1041R on NM_030793.5) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FDXR | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FKBP10 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FPGS | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GATAD2B | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- GPC3 | c.1506_1508del p.E502del | In Frame Del (DEL) | VAF 56/235 reads (24%) | called by mutect2, varscan2
- HMGCR | c.186_188del p.I64del | In Frame Del (DEL) | VAF 37/264 reads (14%) | called by mutect2, pindel, varscan2
- INTU | c.2270A>T p.K757M | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IPO8 | c.3084T>A p.F1028L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ISLR | c.5A>G p.Q2R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- ITPR3 | c.4730C>G p.P1577R | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- JAKMIP1 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCTD16 | c.1205T>C p.F402S | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- KEAP1 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LBR | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- LETMD1 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- LRP1 | c.10342T>A p.C3448S | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRC31 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LYPD5 | c.429_430dup p.D144Gfs*28 (on ENST00000377950 / NM_001031749.3; = p.D101Gfs*28 on NM_182573.2) | Frame Shift Ins (INS) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- LZTS2 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- MACF1 | c.20760T>A p.H6920Q (on ENST00000372915; = p.H4965Q on NM_012090.5) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- MAGEE2 | c.1105A>C p.I369L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MYH2 | c.4544T>A p.I1515N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFIA | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHA8 | c.946del p.Y316Tfs*22 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | called by mutect2, varscan2
- PDZD3 | c.472G>T p.G158* (on ENST00000531114; = p.G92* on NM_024791.4) | Nonsense Mutation (SNP) | VAF 51/191 reads (27%) | called by muse, mutect2, varscan2
- RMI1 | c.504G>C p.L168F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SACM1L | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC26A9 | c.1987C>A p.H663N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STK19 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- STYXL2 | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 27/468 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- SYT7 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TENM4 | c.7717G>T p.A2573S | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.985); called by muse, mutect2
- TOP1 | c.1858A>T p.N620Y | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC29 | c.275A>C p.D92A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UNC13C | c.3357G>T p.W1119C | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- UNC79 | c.731T>A p.L244Q (on ENST00000393151 / NM_001346218.2; = p.L67Q on NM_020818.5) | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- VCX3A | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VSIG1 | c.1041G>C p.E347D | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASF2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM3 | c.275_278del p.F92Sfs*4 | Frame Shift Del (DEL) | VAF 39/178 reads (22%) | called by mutect2, pindel, varscan2
- AC006059.2 | c.252C>T p.H84= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs753389713, COSV59608384; called by muse, mutect2, varscan2
- C3 | c.4053G>A p.K1351= | Silent (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- CACNA1D | c.6000G>C p.L2000= (on ENST00000350061 / NM_001128840.3; = p.L2020= on NM_000720.4) | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- COL5A1 | c.3822A>T p.G1274= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- CSNK1D | c.1125C>A p.R375= | Silent (SNP) | VAF 9/74 reads (12%) | called by mutect2, varscan2
- DST | c.17133G>T p.V5711= (on ENST00000361203 / NM_001374722.1; = p.V3408= on NM_015548.5) | Silent (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- GBE1 | c.1518G>T p.L506= | Silent (SNP) | VAF 14/71 reads (20%) | called by mutect2, varscan2
- GPATCH1 | c.114T>A p.T38= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- HACD2 | c.333G>A p.V111= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- KDM4A | c.1284G>A p.T428= | Silent (SNP) | VAF 61/278 reads (22%) | catalogued as rs770567261, COSV64959044; called by muse, mutect2, varscan2
- KDM4B | c.324T>C p.C108= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- LRRC32 | c.1890C>A p.I630= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV52632230; called by muse, mutect2, varscan2
- NAA38 | c.99C>T p.R33= (on ENST00000575771 / NM_001320925.2; = p.R81= on NM_032356.5) | Silent (SNP) | VAF 16/76 reads (21%) | called by mutect2, varscan2
- NEK8 | c.936G>A p.S312= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as rs146798411; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFIA | c.312T>A p.V104= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- PCDH10 | c.954T>C p.Y318= | Silent (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- PCDHA12 | c.450T>A p.S150= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as rs1554168077; called by muse, mutect2, varscan2
- PCDHB13 | c.888T>C p.N296= | Silent (SNP) | VAF 44/178 reads (25%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1776G>A p.V592= | Silent (SNP) | VAF 55/291 reads (19%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.2118G>A p.A706= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV99532171; called by muse, mutect2, varscan2
- PCNX3 | c.1470G>C p.R490= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- PRRT3 | c.2760C>T p.R920= | Silent (SNP) | VAF 61/236 reads (26%) | called by muse, mutect2, varscan2
- RAB37 | c.414C>T p.I138= (on ENST00000392613 / NM_001006638.3; = p.I131= on NM_175738.5) | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- SEL1L3 | c.2982C>T p.I994= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs776243227; called by muse, mutect2, varscan2
- SMARCA4 | c.504C>T p.G168= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- SVEP1 | c.8223T>C p.Y2741= | Silent (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- TGFB2 | c.864C>G p.S288= | Silent (SNP) | VAF 32/264 reads (12%) | catalogued as rs373646036, COSV65109985; called by muse, mutect2, varscan2
